Surgical pathology report (de-identified scan), TCGA case TCGA-D8-A1JP, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D8-A1JP-01A (Primary Tumor).

1CD-0-3
Carcinoma, infiltrating ductal, NOS 8500/3
Site: breast, NOS C50-9 3/1/11 *h*

page 1 / 1

Department of Cancer Pathology

Copy No.

Date:

Examination: Histopathological examination (cito)

Examination No

Patient: [REDACTED] PESEL: [REDACTED] Age: Gender: F

Material: Multiple organ resection – left breast

Unit in charge:

Physician in charge:

Material collected on: Material received on:

Expected time of examination: 5 working days

Clinical diagnosis:

Examination performed on:

Macroscopic description:

Right breast sized 20.3 x 14.4 x 4.6cm removed, without axillary tissues and with a skin flap of 17.8 x 9.4 cm.

Weight 300g. Site of tumour removal sized 8 x 8 x 3 cm found on the boundary of inner quadrants, placed 4.0 cm from the upper edge, 0.1 cm from the base and 0.2 cm from the skin.

Status after tumour removal (examination No.

Microscopic description:

Status post resectionem tumoris.

Mamilla sine laesionibus.

Glandular tissue showing Parenchyma atrophy.

Histopathological diagnosis:

(Including test No.

Carcinoma ductale invasivum mammae sinistrae. Invasive ductal carcinoma of the left breast.

(NHG2, pT1c, pN0/sn/)

Compliance validated by:

Source: NCI Genomic Data Commons file 4095fa08-6317-4d7b-b650-565ed588e43e (TCGA-D8-A1JP.1B61F1C1-8B19-4D9C-B6B9-87EEE350A472.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).